Gene-level copy-number profile of tumor specimen TCGA-2J-AAB6-01A from TCGA case TCGA-2J-AAB6, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 75.6 years (27,600 days).
Specimen TCGA-2J-AAB6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.8723513c-f687-4f80-9733-4f2cf140822a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2J-AAB6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ab7d975-5649-46dd-80e8-d039a03d1892

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 4,009; copy number 2: 33,799; copy number 3: 16,846; copy number 4: 4,593; copy number 5: 335; copy number 6: 219; copy number 15: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2J-AAB6-01A-11D-A40V-01): tumor purity 0.54, ploidy 2.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,090,898–9,803,784, 3 genes: RPS26P3, RN7SL5P, AL513422.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 569 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,862,123–38,601,200, 71 genes, copy number 6–15 (broad region; genes not listed).
- chr20:19,757,606–26,251,546, 163 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr20:50,292,709–64,313,132, 335 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,081. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
